Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A268, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A268-06A (Metastatic).

ICD-0-3

Melanoma, malignant, NOS 8720/3

Site: lymph node, axillary C77.3 /w 4/27/11

SPECIMENS:

A. LEFT AXILLARY LYMPH NODE

SPECIMEN(S):

A. LEFT AXILLARY LYMPH NODE

GROSS DESCRIPTION:

A. LEFT AXILLARY LYMPH NODE

Received fresh is a 25-g lymph node, 5 x 3.5 x 3 cm. The specimen is sectioned and has a nodular tan cut surface with areas of black discoloration. Portion of the specimen is submitted for tissue procurement. Representative sections are submitted in cassettes A1-A3.

DIAGNOSIS:

A. LEFT AXILLARY LYMPH NODE, EXCISION:
- ONE LYMPH NODE POSITIVE FOR METASTATIC MELANOMA (1/1).

CLINICAL HISTORY:

year old with history of melanoma

PRE-OPERATIVE DIAGNOSIS:

History of melanoma

Gross Dictation:., Pathologist,
Microscopic/Diagnostic Dictation:.,
Final Review:., Pathologist,
Final: Pathologist,

Diagnostic Discrepancy		/

Source: NCI Genomic Data Commons file 1b8ad18b-5725-4e53-a399-1e08fbe6db93 (TCGA-GN-A268.DD8A1957-38F8-4436-8F6A-ADAD5AE479B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).